Somatic mutation profile of tumor specimen C3N-04691-01 (aliquot CPT0293770006) from CPTAC case C3N-04691, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.4 years (22,433 days).
Specimen C3N-04691-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b55c8f3-81de-4b5e-a73b-4320da4e9e8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04691-31 (Blood Derived Normal), aliquot CPT0293790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5558e4e5-642e-410d-b51b-4ead5de6f692

The open-access MAF lists 50 somatic variants for this specimen: 30 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 16, Nonsense Mutation 5, Intron 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs397514532, CM081154, COSV59874078; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CFTR | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as rs121908749, CM126469, CM940236, COSV99141556; ClinVar: pathogenic; called by muse, mutect2
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 17/170 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EVI5L | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs753092741, COSV54484040; called by muse, mutect2
- FBXW10 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1298042791; called by muse, mutect2, varscan2
- LRRIQ1 | c.4914G>T p.Q1638H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV67831561; called by muse, mutect2
- MUC2 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs764883867; called by muse, mutect2, varscan2
- MYH1 | c.5353C>T p.R1785W | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139004562; called by muse, mutect2
- OR4D6 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs201214096; called by muse, mutect2, varscan2
- OR7G3 | c.705T>G p.Y235* | Nonsense Mutation (SNP) | VAF 20/235 reads (9%) | catalogued as rs779919937, COSV59640004; called by muse, mutect2
- PCDHA6 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 136/1168 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as COSV65343926; called by muse, mutect2, varscan2
- SLC6A19 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199999773; called by muse, mutect2, varscan2
- TCP11 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs899863200, COSV99774174; called by muse, mutect2
- TEK | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757379347, COSV66227449; called by muse, mutect2, varscan2
- ZC3H12C | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99585347; called by muse, mutect2
- ZFYVE26 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs758392268, COSV61323913; ClinVar: uncertain significance; called by muse, mutect2
- ARHGAP32 | c.3730A>T p.K1244* (on ENST00000310343 / NM_001378025.1; = p.K895* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 10/157 reads (6%) | called by muse, mutect2
- CPED1 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHX38 | c.2955C>G p.Y985* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2
- DOK4 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- IGHA1 | c.361T>A p.S121T | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2
- LCE1B | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 64/525 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MOV10 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MT1H | c.70T>A p.C24S | Missense Mutation (SNP) | VAF 50/674 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2
- PNMA3 | c.1359G>C p.W453C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPOX | c.1379_1380dup p.E461* | Frame Shift Ins (INS) | VAF 74/694 reads (11%) | called by pindel, varscan2
- SH3RF2 | c.2093G>C p.G698A | Missense Mutation (SNP) | VAF 44/420 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMAD2 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTN | c.95212G>A p.E31738K (on ENST00000591111; = p.E24314K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- ZBTB38 | c.3430C>T p.Q1144* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- CCDC69 | c.630G>A p.L210= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as rs1288529695; called by muse, mutect2, varscan2
- CHSY3 | c.561C>T p.R187= | Silent (SNP) | VAF 36/256 reads (14%) | catalogued as rs1279535909; called by muse, mutect2, varscan2
- CRISP2 | c.348C>T p.D116= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs761357755, COSV59254638, COSV59255869; called by muse, mutect2, varscan2
- CRISP3 | c.645T>A p.P215= (on ENST00000371159 / NM_001368123.1; = p.P197= on NM_006061.4) | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2, varscan2
- DHX38 | c.3663G>A p.T1221= | Silent (SNP) | VAF 36/357 reads (10%) | catalogued as rs765621752, COSV99194279; called by muse, mutect2, varscan2
- ITGB3 | c.2259C>T p.F753= | Silent (SNP) | VAF 29/356 reads (8%) | catalogued as rs546345692, COSV71384884, COSV71385016; called by muse, mutect2
- LRRC47 | c.493C>T p.L165= | Silent (SNP) | VAF 45/359 reads (13%) | catalogued as rs202168763; called by muse, mutect2, varscan2
- MICAL3 | c.810C>T p.F270= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV52905232; called by muse, mutect2
- NUGGC | c.84G>A p.R28= | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- PRAG1 | c.2571C>T p.H857= | Silent (SNP) | VAF 40/439 reads (9%) | catalogued as rs754986834; called by muse, mutect2
- SPEF2 | c.2085G>A p.K695= | Silent (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- TMC6 | c.967C>T p.L323= | Silent (SNP) | VAF 21/264 reads (8%) | catalogued as COSV59808770; called by muse, mutect2
- VSIG10L | c.1932G>A p.L644= | Silent (SNP) | VAF 30/231 reads (13%) | called by muse, mutect2, varscan2
- ZFHX3 | c.8976C>T p.V2992= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as rs752163251; called by muse, mutect2, varscan2
- ZNF215 | c.261T>A p.I87= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as rs747708347; called by muse, mutect2
- ZNF479 | c.1098G>A p.S366= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs372917800; called by muse, mutect2
- AC009053.1 | n.1483G>A | RNA (SNP) | VAF 30/294 reads (10%) | catalogued as rs780448906; called by muse, mutect2
- FXYD6-FXYD2 | c.259+5986C>T | Intron (SNP) | VAF 7/51 reads (14%) | catalogued as rs1412492544, COSV99502700; called by muse, mutect2, varscan2
- LINC01548 | n.329C>T | RNA (SNP) | VAF 20/157 reads (13%) | catalogued as rs113385248; called by mutect2, varscan2
- TTN | c.10360+5267G>A | Intron (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
